Somatic mutation profile of tumor specimen TARGET-40-NAAHDF-02A (aliquot TARGET-40-NAAHDF-02A-01D) from TARGET case TARGET-40-NAAHDF, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.8 years (3,218 days).
Specimen TARGET-40-NAAHDF-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a544e403-347e-47c6-902b-f7561809aa8c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHDF-10A (Blood Derived Normal), aliquot TARGET-40-NAAHDF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dc1220c-821c-4a58-b8ed-abd987cc67eb

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP192 | c.5401C>T p.R1801* | Nonsense Mutation (SNP) | VAF 74/128 reads (58%) | catalogued as rs1254067851, COSV58068319; called by muse, mutect2, varscan2
- DMD | c.5567C>A p.T1856K | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs148246460; called by muse, varscan2
- MUC4 | c.5375G>C p.R1792P | Missense Mutation (SNP) | VAF 59/484 reads (12%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.318); catalogued as rs774527434; called by muse, varscan2
- ZHX3 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs758030114; called by muse, mutect2, varscan2
- FAM186A | c.3294G>T p.T1098= | Silent (SNP) | VAF 23/237 reads (10%) | catalogued as rs1338401841; called by muse, varscan2
- SYNE1 | c.7986A>G p.K2662= (on ENST00000367255 / NM_182961.4; = p.K2669= on NM_033071.3) | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
